Somatic mutation profile of tumor specimen 0DE5QZ from CCDI case PBBPAJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Age at diagnosis: 20.1 years (7,329 days).
Specimen 0DE5QZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b36b56c-d30f-41e6-861e-0d657b8d6fe4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE5NA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7df6ff6-9db8-43a3-8eb3-da326218597c

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 2, Frame Shift Ins 2, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.4379dup p.N1460Kfs*2 | Frame Shift Ins (INS) | VAF 40/146 reads (27%) | catalogued as rs387906455; ClinVar: pathogenic; called by mutect2, varscan2
- CD1E | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 122/483 reads (25%) | catalogued as rs770576446, COSV63770265, COSV63773170; called by muse, varscan2
- EEF1AKMT4-ECE2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 92/162 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs371866621, COSV62567482; called by muse, mutect2, varscan2
- FAM13A | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs895101380; called by muse, mutect2, varscan2
- MGAM | c.4384C>G p.L1462V | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as COSV72075244; called by muse, mutect2, varscan2
- NFXL1 | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 82/418 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs140512787; called by muse, mutect2, varscan2
- OR4Q3 | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV59177262, COSV59177487; called by mutect2, varscan2
- SFTPC | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 120/598 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.872); catalogued as rs75902455; called by mutect2, varscan2
- THOC2 | c.4766C>T p.S1589L | Missense Mutation (SNP) | VAF 231/472 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.084); catalogued as rs752066937; called by muse, mutect2, varscan2
- ABCC10 | c.784del p.V262Sfs*30 (on ENST00000372530 / NM_001198934.2; = p.V219Sfs*30 on NM_033450.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 129/373 reads (35%) | called by mutect2, varscan2
- ATP2B3 | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 142/439 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DESI1 | c.78dup p.I27Hfs*21 | Frame Shift Ins (INS) | VAF 158/374 reads (42%) | called by mutect2, varscan2
- DNAJC6 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FUNDC2 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 120/538 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- MAP7 | c.1359G>A p.M453I | Missense Mutation (SNP) | VAF 31/512 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- NR2F2 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- H2AC4 | c.174C>T p.Y58= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as rs199820035; called by muse, mutect2
- PCDHB10 | c.963A>G p.A321= | Silent (SNP) | VAF 64/406 reads (16%) | called by muse, mutect2, varscan2
- PEG10 | c.186C>T p.R62= (on ENST00000482108 / NM_001040152.2; = p.R96= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/243 reads (19%) | called by muse, mutect2, varscan2
- RAC2 | c.561C>T p.R187= | Silent (SNP) | VAF 79/394 reads (20%) | catalogued as rs201536161; called by muse, mutect2, varscan2
- RSAD2 | c.573T>A p.I191= | Silent (SNP) | VAF 111/657 reads (17%) | called by muse, mutect2, varscan2
- UBAP2 | c.1470T>C p.N490= | Silent (SNP) | VAF 119/679 reads (18%) | catalogued as rs752631866; called by muse, mutect2, varscan2
- FA2H | c.613+82G>A | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
- FAM32A | chr19:16185382 G>T | 5'Flank (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- MORF4L1 | c.920-74C>T | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- NOS1 | c.*88G>A | 3'UTR (SNP) | VAF 95/157 reads (61%) | called by muse, mutect2, varscan2
